Gene-level copy-number profile of tumor specimen CDDP-ABL4-TTP1-A from CDDP_EAGLE case CDDP-ABL4, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 44 years.
Specimen CDDP-ABL4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 51256557-d8ae-441d-9709-b2c7dd30e17e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ABL4-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/0b21a455-a0e8-42ea-a4c5-b664f03461eb

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 204; copy number 1: 698; copy number 2: 322; copy number 3: 4,976; copy number 4: 25,910; copy number 5: 6,854; copy number 6: 11,907; copy number 7: 1,834; copy number 8: 1,436; copy number 9: 2,288; copy number 10: 57; copy number 11: 290; copy number 12: 439; copy number 13: 911; copy number 14: 3; copy number 15: 218; copy number 17: 9; copy number 21: 2; copy number 26: 12; copy number 34: 9; copy number 35: 16.

Homozygous deletions (total copy number 0; autosomes only): 196 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:12,134–73,865, 5 genes (within-gene range 0–4): DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C.
- chr9:21,206,181–31,645,160, 115 genes (broad region; genes not listed).
- chr9:37,836,044–37,904,353, 4 genes (within-gene range 0–4): AL138752.1, PAICSP1, SLC25A51, TMX2P1.
- chr9:37,936,707–40,333,460, 60 genes (within-gene range 0–4): RNU7-124P, U8, AL135785.1, ALDH1B1, IGFBPL1, AL390726.5, ARMC8P1, TCEA1P3, GAS2L1P1, VN1R48P, AL390726.1, FAM220BP, AL390726.4, FAM95C, AL390726.3, AL390726.2, SNX18P3, ANKRD18A, FAM201A, YWHABP1, RNU6-765P, AL845311.1, VN2R3P, CNTNAP3, RBM17P1, AL353729.2, AL353729.1, RN7SL640P, SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3, FKBP4P2, SDR42E1P1, ATP5F1AP8, RAB28P1, RBPJP5, GLIDR, BX664615.1, FGF7P3, BX664615.2, RN7SL763P, SNORA70, CR769767.1, AL772307.1, RPL7AP49, AL773545.3, CDRT15P14, AL773545.1, AL773545.2, ANKRD20A2P, BX664727.3, RNU6-1269P, BX664727.2, SNX18P8, FAM95B1, BX664727.1.
- chr9:61,190,003–61,662,690, 11 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr12:164,664–166,321, 1 gene (within-gene range 0–1): AC026369.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,254 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,450,245, 3 genes, copy number 9: AC239859.5, RNA5SP533, AC239859.3.
- chr1:143,541,768–143,720,644, 6 genes, copy number 13: AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23.
- chr3:75,084,155–78,294,731, 45 genes, copy number 12 (within-gene range 12–19): NIPA2P2, RN7SL294P, MIR4444-2, AC117481.1, HNRNPA3P6, MYLKP1, OR7E66P, OR7E22P, OR7E55P, AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1, OR7E121P, UNC93B3, RPL23AP49, AC108724.2, CLUHP10, MIR1324, AGGF1P3, RARRES2P1, FRG2C, DUX4L26, LINC00960, ZNF717, MIR4273, ROBO2, Y_RNA, CAP1P1, RNU6-386P, VDAC1P7, AC133040.1, RNU6-217P, LINC02077, AC117462.1, RN7SL647P, RN7SKP61, AC108752.1.
- chr3:84,638,405–90,261,708, 46 genes, copy number 12: LINC00971, AC117482.1, LINC02025, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr5:58,198–38,845,829, 581 genes, copy number 11–12 (broad region; genes not listed).
- chr7:63,011,463–159,233,377, 1,898 genes, copy number 9–21 (broad region; genes not listed).
- chr8:46,028,804–133,134,903, 1,235 genes, copy number 9 (broad region; genes not listed).
- chr8:133,573,183–145,066,685, 251 genes, copy number 9 (broad region; genes not listed).
- chr9:61,944,232–61,945,136, 1 gene, copy number 12: CR769775.1.
- chr12:166,856–991,190, 21 genes, copy number 26–34 (within-gene range 1–34): AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1.
- chr12:26,623,369–28,825,831, 46 genes, copy number 10: AC023051.1, AC023051.2, INTS13, FGFR1OP2, TM7SF3, AC024896.1, MED21, AC092747.4, C12orf71, AC092747.3, AC092747.1, AC092747.2, STK38L, ARNTL2, ARNTL2-AS1, SMCO2, RARS1P1, PPFIBP1, AC087257.1, AC087257.2, AC009509.3, AC009509.1, REP15, AC009509.4, HMGB1P49, AC009509.2, MRPS35, Y_RNA, MANSC4, AC009511.2, KLHL42, AC009511.1, RN7SKP15, AC009511.3, AC008011.1, PTHLH, AC008011.2, CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P, RNA5SP355, AC084754.1, AC022081.1.
- chr12:31,244,440–33,439,819, 67 genes, copy number 11–35 (broad region; genes not listed).
- chr14:18,333,726–18,596,310, 8 genes, copy number 10: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9.
- chr19:43,153,279–43,207,299, 3 genes, copy number 10: AC005392.1, PSG5, PSG4.
- chr20:25,919,499–26,251,546, 13 genes, copy number 11: CFTRP1, LINC01733, FAM182A, AL078587.1, AL078587.2, AL450124.1, BSNDP3, NCOR1P1, AL391119.1, AL121904.2, MIR663AHG, AL121904.1, MIR663A.
- chr20:31,421,436–31,723,989, 18 genes, copy number 15: DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON.
- chr20:33,490,075–33,731,828, 10 genes, copy number 14–17 (within-gene range 6–17): CBFA2T2, AL121906.2, NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1, E2F1, PXMP4, AL050349.1.
- chr20:33,965,162–33,994,357, 2 genes, copy number 14 (within-gene range 5–14): PIGPP3, RALY-AS1.

Autosomal genes at a single copy (total copy number 1): 85. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
